CCDI case PBCCDF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/20915136-c760-4bd8-b47e-b7c78188edb8

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Myofibroblastic tumor, NOS: ICD-O-3 morphology code: 8825/1; Tissue or organ of origin: Cecum; Age at diagnosis: 1.0 years (381 days).

Biospecimens (3 samples)
- Sample 0DO5DZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DO5EY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DO5FQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
